Somatic mutation profile of tumor specimen TCGA-05-5425-01A (aliquot TCGA-05-5425-01A-02D-1625-08) from TCGA case TCGA-05-5425, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.5 years (25,020 days).
Specimen TCGA-05-5425-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5adc5a1-38a7-46c5-a65e-d4cf08c3cf3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-5425-10A (Blood Derived Normal), aliquot TCGA-05-5425-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97975bd4-2fb8-460f-812b-bea62e380149

The open-access MAF lists 602 somatic variants for this specimen: 452 protein-altering or splice-affecting, 133 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 390, Silent 133, Nonsense Mutation 38, Splice Site 10, Intron 9, Frame Shift Del 7, Frame Shift Ins 3, 5'Flank 3, RNA 2, 5'UTR 2, In Frame Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121908596, CM080433, COSV61068347, COSV61068483; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYO9A | c.3898C>T p.P1300S | Missense Mutation (SNP) | VAF 40/110 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.964); catalogued as COSV61847987; called by muse, mutect2, varscan2
- TP53 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 42/123 reads (34%) | catalogued as rs869312782, COSV52692559, COSV52721885, COSV53153630, COSV53758203; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1577T>A p.L526* (on ENST00000272895 / NM_173076.3; = p.L208* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 7/96 reads (7%) | catalogued as COSV55958540; called by muse, mutect2
- ABHD17B | c.358T>A p.C120S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV61007898; called by mutect2, varscan2
- AC098582.1 | c.2554T>A p.C852S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV52020027, COSV99986132; called by muse, mutect2, varscan2
- ACCSL | c.40C>G p.Q14E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV66581145; called by muse, mutect2, varscan2
- ACTN2 | c.530A>G p.H177R | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV63974787; called by muse, mutect2
- ADAM23 | c.1364C>A p.S455Y | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as rs1458369826, COSV52214804, COSV52216093; called by muse, mutect2
- ADAMTS12 | c.1724A>C p.K575T | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV61260128, COSV61272004; called by muse, mutect2
- ADAMTS12 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.845); catalogued as COSV61262447; called by muse, mutect2, varscan2
- ADAMTS20 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs747342811, COSV67131114; called by muse, mutect2, varscan2
- ADGRD1 | c.93G>T p.Q31H | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV55444719; called by muse, mutect2, varscan2
- ADGRL3 | c.2501C>T p.T834M (on ENST00000506720 / NM_001322402.2; = p.T766M on NM_015236.6) | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.75); catalogued as rs376555701, COSV101547454, COSV99072522; called by muse, mutect2
- ADH1B | c.250G>T p.V84F | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.145); catalogued as rs762335814, COSV59296317; called by muse, mutect2, varscan2
- ADH7 | c.224C>A p.P75Q | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52920740; called by muse, mutect2, varscan2
- AGAP2 | c.2232C>G p.I744M (on ENST00000547588 / NM_001122772.2; = p.I408M on NM_014770.4) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.176); catalogued as COSV57728020; called by muse, mutect2
- AHNAK | c.11383G>T p.V3795F | Missense Mutation (SNP) | VAF 112/270 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV57212727; called by muse, mutect2, varscan2
- AHNAK2 | c.5117T>A p.L1706H | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV100318794; called by muse, mutect2, varscan2
- AIM2 | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV63699814; called by muse, mutect2, varscan2
- AKAP14 | c.329G>A p.S110N | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV57630089; called by muse, mutect2, varscan2
- AKAP3 | c.1303T>A p.Y435N | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.425); catalogued as COSV57416459; called by muse, mutect2
- AL117348.2 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | PolyPhen benign (0.005); catalogued as COSV55282902; called by muse, mutect2, varscan2
- ALKAL1 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1024398355, COSV62130319; called by muse, mutect2, varscan2
- AMPH | c.2072C>A p.T691N | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57741260; called by muse, mutect2, varscan2
- ANGPT1 | c.1226C>A p.T409N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV52439320; called by muse, mutect2, varscan2
- AOAH | c.1595A>T p.N532I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV51740799; called by muse, mutect2, varscan2
- AP1M1 | c.1150T>A p.Y384N | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52226408; called by muse, mutect2
- ARFGEF1 | c.4331A>C p.Q1444P | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as COSV51608019; called by muse, mutect2, varscan2
- ARID5B | c.1540C>A p.P514T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV54419984, COSV54429842; called by muse, mutect2, varscan2
- ARL2 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.57); catalogued as COSV55861229; called by muse, mutect2, varscan2
- ASB17 | c.809C>A p.T270N | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99408047; called by muse, mutect2, varscan2
- ASNS | c.1586G>T p.R529L | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV51552187; called by muse, mutect2, varscan2
- ATOH1 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV60037896; called by muse, mutect2
- ATP1A2 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756853546, COSV63403442, COSV63403655; called by muse, mutect2, varscan2
- ATP2B3 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV54846586; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1611G>T p.W537C | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57749153; called by muse, mutect2, varscan2
- ATP7B | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs2277447, COSV54438206; called by muse, mutect2, varscan2
- BAMBI | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV65002964; called by muse, mutect2
- BLK | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | catalogued as COSV52051944; called by muse, mutect2, varscan2
- BMS1 | c.3599G>T p.R1200L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as COSV65732794, COSV65733808; called by muse, mutect2, varscan2
- C12orf42 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV59382490; called by muse, mutect2, varscan2
- C12orf66 | c.545C>A p.P182H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV61323122; called by muse, mutect2, varscan2
- C12orf66 | c.61T>A p.F21I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV61323130; called by muse, mutect2
- C16orf70 | c.1108A>T p.R370W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54627192; called by muse, mutect2, varscan2
- C6orf118 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV57814793; called by muse, mutect2, varscan2
- CARD11 | c.1381G>T p.D461Y | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV62755198; called by muse, mutect2, varscan2
- CARD6 | c.1469A>T p.D490V | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54566084; called by muse, varscan2
- CBX1 | c.506C>A p.T169K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56681836; called by muse, mutect2, varscan2
- CCDC172 | c.448+1G>T p.X150_splice | Splice Site (SNP) | VAF 28/82 reads (34%) | catalogued as rs1166209396, COSV60937691; called by muse, mutect2, varscan2
- CCDC74A | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs781391784, COSV54606562; called by muse, mutect2, varscan2
- CCN4 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51531476, COSV51532907; called by mutect2, varscan2
- CDH10 | c.1988G>T p.G663V | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52580048; called by muse, mutect2, varscan2
- CDH11 | c.2210A>G p.Y737C | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51761031; called by muse, mutect2, varscan2
- CDH17 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.098); catalogued as COSV50328258; called by muse, mutect2, varscan2
- CDH23 | c.5395G>A p.G1799R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56462315; called by muse, mutect2
- CDH6 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 18/232 reads (8%) | catalogued as COSV54069333; called by muse, mutect2
- CDH7 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.248); catalogued as COSV59885824; called by muse, mutect2
- CDKL2 | c.980A>G p.D327G | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); catalogued as rs200524804, COSV56733426; called by mutect2, varscan2
- CELSR3 | c.6336T>A p.S2112R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV50857369; called by muse, mutect2, varscan2
- CEP170 | c.2037G>T p.E679D | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV60508837; called by muse, mutect2
- CFH | c.752G>C p.C251S | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62777362; called by muse, mutect2, varscan2
- CILP | c.2983G>A p.D995N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56024130; called by muse, mutect2, varscan2
- CILP | c.1292G>T p.R431L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.173); catalogued as rs776061400, COSV56023546, COSV56024144; called by muse, mutect2, varscan2
- CLCA2 | c.233G>T p.R78I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV65287078; called by muse, mutect2, varscan2
- CLDN10 | c.596C>A p.S199Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.931); catalogued as COSV54824233; called by muse, mutect2, varscan2
- CLEC4F | c.990A>T p.E330D | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV55479235; called by muse, mutect2, varscan2
- CLEC7A | c.403A>T p.S135C (on ENST00000304084 / NM_197947.3; = p.S89C on NM_022570.5) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs1422790966, COSV53722272; called by muse, mutect2, varscan2
- CNNM1 | c.2026C>T p.Q676* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV63201458; called by muse, mutect2, varscan2
- CNTN1 | c.1958A>T p.K653M | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV61639453; called by muse, mutect2, varscan2
- CNTN6 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV100610401, COSV63171358; called by muse, mutect2
- CNTNAP5 | c.2118G>T p.R706S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.033); catalogued as rs369688023; called by mutect2, varscan2
- CNTNAP5 | c.2505A>T p.K835N | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV70484946; called by muse, varscan2
- COL27A1 | c.1637G>A p.G546E | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV61925786; called by muse, mutect2, varscan2
- COL4A1 | c.4851C>A p.H1617Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV101011514, COSV65423331; called by muse, mutect2, varscan2
- COL4A1 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65425276; called by muse, mutect2, varscan2
- COL6A1 | c.1003-2A>T p.X335_splice | Splice Site (SNP) | VAF 19/59 reads (32%) | catalogued as CS151669, COSV62613032; called by muse, mutect2, varscan2
- COL7A1 | c.4342-2A>T p.X1448_splice | Splice Site (SNP) | VAF 4/41 reads (10%) | catalogued as CS120667, COSV60394946; called by muse, mutect2, varscan2
- CPA1 | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV50569519; called by muse, mutect2, varscan2
- CPA3 | c.970C>T p.H324Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV56045051; called by muse, mutect2, varscan2
- CPA5 | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV62569548; called by muse, mutect2, varscan2
- CPS1 | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV51805211; called by muse, mutect2
- CRB1 | c.3655C>A p.Q1219K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV66330205; called by muse, mutect2, varscan2
- CSMD3 | c.9013G>T p.V3005F (on ENST00000297405 / NM_001363185.1; = p.V2836F on NM_052900.3) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV52173600; called by muse, mutect2, varscan2
- CSMD3 | c.917+1G>A p.X306_splice | Splice Site (SNP) | VAF 3/47 reads (6%) | catalogued as COSV52173635, COSV52302408; called by muse, mutect2
- CWC27 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66885701; called by muse, mutect2, varscan2
- DBH | c.27C>A p.S9R | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.035); catalogued as COSV55040684, COSV99707876; called by muse, varscan2
- DCAF4L2 | c.401C>A p.S134* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as COSV60478498; called by muse, mutect2, varscan2
- DEFA3 | c.270G>T p.W90C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV59935120; called by mutect2, varscan2
- DEFB110 | c.39G>T p.W13C | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV64484486; called by muse, mutect2
- DLC1 | c.4468G>C p.G1490R (on ENST00000276297 / NM_001348081.2; = p.G1053R on NM_006094.5) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52302718; called by muse, mutect2
- DLG2 | c.1210C>A p.Q404K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV54642315; called by muse, mutect2, varscan2
- DLGAP5 | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55963156; called by muse, mutect2, varscan2
- DMBT1 | c.3166G>T p.V1056F (on ENST00000338354 / NM_001377530.1; = p.V557F on NM_004406.3) | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.97); catalogued as COSV57543389; called by muse, mutect2, varscan2
- DMD | c.1447C>A p.L483I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as COSV55869272; called by muse, mutect2, varscan2
- DMD | c.1040C>A p.A347D | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV55869295; called by muse, mutect2, varscan2
- DMRT2 | c.555T>A p.N185K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.185); catalogued as COSV52401815; called by muse, mutect2, varscan2
- DNAH7 | c.5257G>T p.E1753* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV56763793, COSV56770131; called by muse, mutect2
- DNMT3B | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52418275; called by muse, mutect2, varscan2
- DRD3 | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); catalogued as COSV55680089; called by muse, mutect2, varscan2
- DSCAML1 | c.3526C>A p.R1176S (on ENST00000321322; = p.R1116S on NM_020693.4) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100356200, COSV58390029; called by muse, mutect2, varscan2
- DSG3 | c.2128G>T p.G710C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57126091; called by muse, mutect2
- DST | c.7524G>T p.Q2508H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.124); catalogued as COSV99759431; called by muse, mutect2, varscan2
- DYRK3 | c.821T>C p.M274T | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV65606181; called by muse, mutect2, varscan2
- EPB41L4B | c.2434G>C p.V812L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV65803032; called by muse, mutect2, varscan2
- EPHA5 | c.1191G>C p.K397N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV56643909; called by muse, mutect2, varscan2
- EPHA5 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56643924, COSV99901013; called by muse, mutect2, varscan2
- EPHA6 | c.1106C>A p.S369Y | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.891); catalogued as COSV67565884, COSV67571155; called by muse, mutect2, varscan2
- EPHA6 | c.2573G>T p.R858L (on ENST00000389672 / NM_001080448.3; = p.R250L on NM_173655.4) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV67571163; called by muse, mutect2, varscan2
- ERG | c.94A>T p.T32S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV55731779; called by muse, mutect2, varscan2
- ERICH3 | c.3348A>T p.K1116N | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV58606078; called by muse, mutect2, varscan2
- ERMARD | c.242A>T p.H81L | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64650283; called by muse, mutect2, varscan2
- ESD | c.549G>C p.W183C | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66340198; called by muse, mutect2, varscan2
- ESPL1 | c.3877G>T p.G1293C | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV57759299; called by muse, mutect2, varscan2
- EVPL | c.463G>T p.V155L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV101648803, COSV56910692; called by muse, mutect2, varscan2
- EXPH5 | c.2450G>A p.R817K | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.329); catalogued as COSV56202046; called by muse, mutect2
- EXTL1 | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as rs372060207; called by muse, mutect2, varscan2
- EXTL2 | c.940A>G p.I314V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.072); catalogued as rs746758819, COSV64473056; called by muse, mutect2, varscan2
- F13A1 | c.564G>T p.W188C | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53558116; called by muse, mutect2
- FAM114A2 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV61077809; called by muse, mutect2, varscan2
- FAM135B | c.3253G>T p.D1085Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV52745589, COSV52748374; called by muse, mutect2, varscan2
- FAM83H | c.781G>T p.V261L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.135); catalogued as COSV66353860, COSV66354082; called by muse, mutect2, varscan2
- FANCM | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV53532315; called by muse, mutect2, varscan2
- FASTKD1 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | catalogued as COSV101328541; called by muse, mutect2
- FAT3 | c.9008C>A p.T3003N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53107235; called by muse, varscan2
- FBL | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV55682559; called by muse, mutect2, varscan2
- FBN2 | c.5214C>A p.S1738R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV52511324; called by muse, mutect2, varscan2
- FBXO24 | c.555G>T p.K185N (on ENST00000241071 / NM_033506.3; = p.K223N on NM_012172.5) | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53825829, COSV53826170; called by muse, mutect2, varscan2
- FGD5 | c.1198C>G p.L400V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV53242313, COSV99548036; called by muse, mutect2, varscan2
- FICD | c.518A>T p.H173L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV57207218; called by muse, mutect2, varscan2
- FLNC | c.5567C>A p.A1856D | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.67); catalogued as COSV57955529; called by muse, mutect2, varscan2
- FOXJ2 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV50818682; called by muse, mutect2, varscan2
- FOXP2 | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV63485781; called by muse, mutect2, varscan2
- FOXRED1 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55006441; called by muse, mutect2, varscan2
- GABRA4 | c.1538C>A p.S513Y | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV51927243; called by muse, mutect2, varscan2
- GABRB3 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV54663060; called by muse, mutect2, varscan2
- GABRG1 | c.746T>C p.I249T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.3); catalogued as COSV54953740; called by muse, mutect2, varscan2
- GBP4 | c.1867C>A p.P623T | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV63254207; called by muse, mutect2, varscan2
- GBP6 | c.1261A>G p.I421V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.381); catalogued as COSV65011432; called by muse, mutect2, varscan2
- GEN1 | c.897G>T p.E299D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100438177; called by muse, mutect2, varscan2
- GIMAP5 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100500294, COSV57530608; called by muse, mutect2, varscan2
- GLG1 | c.1233A>G p.R411= | Splice Region (SNP) | VAF 4/36 reads (11%) | catalogued as COSV52666746; called by muse, mutect2
- GLP2R | c.742G>T p.G248W | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV52324653; called by muse, mutect2, varscan2
- GOLGA4 | c.2249C>T p.T750I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1328833149, COSV62710584; called by muse, mutect2, varscan2
- GOSR1 | c.241-2A>G p.X81_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | catalogued as COSV56719031; called by muse, mutect2
- GPAM | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV62081052; called by muse, mutect2, varscan2
- GPI | c.1022A>G p.Y341C | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs373311425; called by muse, mutect2, varscan2
- GPR158 | c.2899C>A p.P967T | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV66269625, COSV66276035; called by muse, mutect2, varscan2
- GPR183 | c.346T>A p.Y116N | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63117937; called by muse, mutect2, varscan2
- GPR45 | c.947A>T p.K316M | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51523831, COSV51524424, COSV51524440; called by muse, mutect2, varscan2
- GPSM2 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1012841600, COSV51442377; called by muse, mutect2, varscan2
- GRHL2 | c.120G>T p.L40F | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52548156; called by muse, mutect2, varscan2
- GRIK3 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1365978193, COSV66139515; called by muse, mutect2, varscan2
- GRM4 | c.2500C>A p.L834M | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV65213108; called by muse, mutect2, varscan2
- GRM5 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.516); catalogued as COSV59603930; called by muse, mutect2, varscan2
- GSR | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55320565; called by muse, mutect2, varscan2
- HAUS1 | c.754C>G p.Q252E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV56363327; called by muse, mutect2, varscan2
- HBA2 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV52406538; called by muse, mutect2, varscan2
- HDX | c.665T>C p.I222T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV52976387; called by muse, mutect2, varscan2
- HECTD1 | c.7789C>T p.R2597C | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67946225; called by muse, mutect2
- HECW1 | c.2992G>T p.E998* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV67828851; called by muse, mutect2, varscan2
- HEPH | c.2224G>A p.V742I (on ENST00000343002; = p.V475I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV57963459; called by muse, mutect2, varscan2
- HGF | c.1578G>T p.E526D | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV55949285; called by muse, mutect2, varscan2
- HHEX | c.515A>T p.K172M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51106110; called by muse, mutect2, varscan2
- HOXA4 | c.662C>A p.A221D | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57826257; called by muse, mutect2, varscan2
- HOXB3 | c.649C>G p.R217G | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV57486733, COSV57487505; called by muse, mutect2
- HRNR | c.2237C>G p.S746* | Nonsense Mutation (SNP) | VAF 54/238 reads (23%) | catalogued as COSV64257634; called by muse, mutect2
- HRNR | c.1276C>A p.H426N | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1557845746, COSV64257642; called by muse, mutect2, varscan2
- HSPA12A | c.335A>T p.H112L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV65022209; called by muse, mutect2
- HTR2A | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 57/335 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66327238; called by muse, mutect2, varscan2
- HTRA1 | c.1096del p.E366Sfs*22 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | catalogued as COSV64563957; called by mutect2, pindel
- IFT172 | c.4688C>G p.S1563* | Nonsense Mutation (SNP) | VAF 5/73 reads (7%) | catalogued as COSV51994103; called by muse, mutect2
- IGDCC4 | c.2408+1G>T p.X803_splice | Splice Site (SNP) | VAF 10/65 reads (15%) | catalogued as COSV61536741; called by muse, mutect2, varscan2
- IGKV1-27 | c.48G>T p.W16C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as rs539140111; called by muse, mutect2, varscan2
- IGSF10 | c.2783T>A p.I928N | Missense Mutation (SNP) | VAF 9/305 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as COSV56784910; called by muse, mutect2
- IKBKB | c.389-2A>T p.X130_splice | Splice Site (SNP) | VAF 5/35 reads (14%) | catalogued as COSV60597275; called by muse, mutect2, varscan2
- INSRR | c.2563C>A p.R855S | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.763); catalogued as COSV63872917, COSV63878698; called by muse, mutect2, varscan2
- ITGA4 | c.1457G>C p.C486S | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52000057; called by muse, mutect2
- ITGA7 | c.1324G>T p.D442Y (on ENST00000555728; = p.D398Y on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57695029; called by muse, mutect2
- ITGA8 | c.1846G>T p.G616C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV65228497; called by muse, mutect2
- ITIH2 | c.1701T>A p.D567E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV64433056; called by muse, mutect2, varscan2
- ITIH2 | c.1847C>A p.S616Y | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64433061; called by muse, mutect2, varscan2
- KALRN | c.4691A>G p.N1564S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1033137258, COSV53762921; called by muse, mutect2, varscan2
- KARS1 | c.1213G>T p.G405W | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs374802658, COSV56692048; called by muse, mutect2, varscan2
- KCNA4 | c.1079A>T p.E360V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV60252029; called by muse, mutect2
- KCNH5 | c.1676T>G p.L559R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as COSV59759494; called by muse, mutect2, varscan2
- KDM2A | c.2636A>G p.N879S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.048); catalogued as COSV58189574; called by muse, mutect2, varscan2
- KERA | c.628A>G p.R210G | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57130584; called by muse, mutect2
- KIF6 | c.2035C>T p.Q679* | Nonsense Mutation (SNP) | VAF 14/145 reads (10%) | catalogued as COSV54676415; called by muse, mutect2
- KIR2DL3 | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 54/321 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV60897196; called by muse, mutect2, varscan2
- KLHDC8B | c.594G>C p.E198D | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV60411775; called by muse, mutect2, varscan2
- KLHL6 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as COSV58066292; called by muse, mutect2, varscan2
- KMT2D | c.16281T>G p.I5427M | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56437776; called by muse, mutect2
- KRT5 | c.770A>T p.K257M | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52860568; called by muse, mutect2, varscan2
- KRTAP26-1 | c.261C>A p.Y87* | Nonsense Mutation (SNP) | VAF 40/119 reads (34%) | catalogued as COSV62128579, COSV62128769; called by muse, mutect2, varscan2
- KRTAP5-10 | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.07); catalogued as rs1241787002, COSV64794685; called by muse, mutect2
- LCA5 | c.1636G>T p.A546S | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.085); catalogued as COSV63971283, COSV63973272; called by muse, mutect2, varscan2
- LEF1 | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54466996; called by muse, mutect2, varscan2
- LENG8 | c.1875G>T p.E625D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV58727630; called by muse, mutect2, varscan2
- LFNG | c.607A>T p.N203Y (on ENST00000222725 / NM_001040167.2; = p.N74Y on NM_002304.2) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56069322; called by muse, mutect2, varscan2
- LILRA4 | c.646C>A p.L216M | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52492145; called by muse, mutect2
- LILRA4 | c.203C>A p.S68* | Nonsense Mutation (SNP) | VAF 20/118 reads (17%) | catalogued as rs748802900, COSV52492158, COSV52495085; called by muse, mutect2, varscan2
- LLGL1 | c.2116G>T p.V706L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV100375632, COSV57498673; called by muse, mutect2, varscan2
- LMNTD1 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs773815123, COSV51446703; called by muse, mutect2, varscan2
- LPA | c.2650C>A p.P884T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60301472, COSV60313538; called by muse, mutect2, varscan2
- LRIG3 | c.3311T>C p.L1104S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as rs745582642, COSV57863440; called by muse, mutect2, varscan2
- LRP1B | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as COSV67216532; called by muse, mutect2, varscan2
- LUM | c.602C>G p.S201C | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV57128066; called by muse, mutect2
- LYST | c.8882G>T p.R2961L | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs375783616, COSV67707746; called by muse, mutect2, varscan2
- MAB21L2 | c.930C>A p.C310* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100462413; called by muse, mutect2, varscan2
- MAGEB18 | c.92C>A p.T31N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100305614, COSV57463667; called by mutect2, varscan2
- MAP2 | c.347A>G p.H116R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as COSV52290170; called by muse, mutect2
- MAPK7 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV100219073; called by muse, mutect2
- MBOAT2 | c.221G>T p.W74L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60008975; called by muse, mutect2, varscan2
- MCHR2 | c.473G>T p.W158L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56002590; called by muse, mutect2
- MED23 | c.3364G>T p.V1122F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63432397; called by mutect2, varscan2
- MERTK | c.1212A>T p.R404S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV54928694; called by muse, mutect2
- MLXIP | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59835168; called by muse, mutect2
- MMS22L | c.430T>C p.Y144H | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as COSV99247618; called by muse, mutect2
- MOCS1 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866399151, COSV57933878; called by muse, mutect2, varscan2
- MROH2B | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68183760; called by muse, mutect2, varscan2
- MRPL27 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.27); catalogued as COSV56812464; called by muse, mutect2, varscan2
- MS4A14 | c.718T>A p.S240T | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV55734755; called by muse, mutect2, varscan2
- MTCL1 | c.2539G>T p.G847C (on ENST00000306329 / NM_001378206.1; = p.G487C on NM_015210.4) | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as rs1330467361, COSV60405879; called by muse, mutect2, varscan2
- MTR | c.927G>T p.K309N | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as COSV63967938, COSV63968446; called by muse, mutect2, varscan2
- MUC16 | c.36960G>A p.W12320* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | catalogued as COSV67464028; called by muse, mutect2, varscan2
- MUC16 | c.22007C>T p.T7336I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV67464029; called by mutect2, varscan2
- MUC16 | c.7036G>C p.E2346Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV67444208, COSV67464032; called by muse, mutect2, varscan2
- MUC16 | c.3599C>A p.S1200Y | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.85); catalogued as COSV67464034, COSV67490566; called by muse, mutect2, varscan2
- MUC3A | c.8756C>A p.T2919N | Missense Mutation (SNP) | VAF 21/263 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs752897005, COSV100115306; called by muse, mutect2
- MUC6 | c.3133G>C p.D1045H | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV70141143; called by muse, mutect2
- MYH13 | c.5626C>A p.Q1876K | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99355263; called by muse, mutect2
- MYH13 | c.3559C>A p.L1187M | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV99355264; called by muse, mutect2, varscan2
- MYH8 | c.2178G>T p.K726N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV67964609; called by mutect2, varscan2
- MYH9 | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as rs1343411512, COSV53385849; called by muse, mutect2, varscan2
- MYO1H | c.1645G>T p.V549L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.412); catalogued as COSV100183941; called by muse, mutect2
- NAE1 | c.1297G>C p.D433H | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV51976257; called by muse, mutect2
- NALCN | c.4970C>A p.A1657E | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0.011); catalogued as COSV51933940; called by muse, mutect2, varscan2
- NCSTN | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54187479; called by muse, mutect2, varscan2
- NDST4 | c.292A>G p.I98V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.12); catalogued as COSV52118946, COSV99997949; called by muse, mutect2, varscan2
- NGLY1 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99770884; called by muse, mutect2
- NKX2-5 | c.947C>A p.S316Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100234887; called by muse, mutect2, varscan2
- NLRP13 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs199475874, COSV61621567; ClinVar: not provided; called by muse, mutect2, varscan2
- NMUR1 | c.942C>A p.H314Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59403590, COSV59404176; called by mutect2, varscan2
- NPFFR2 | c.1306G>A p.G436S | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV58148755; called by muse, mutect2, varscan2
- NRG3 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs149882313, COSV100932482, COSV100932524; called by muse, mutect2
- NRXN1 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as COSV68014715; called by muse, mutect2, varscan2
- NRXN3 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs539329038, COSV73583739; called by muse, mutect2, varscan2
- NRXN3 | c.2621C>T p.T874I (on ENST00000335750 / NM_001330195.2; = p.T501I on NM_004796.6) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs763450991, COSV59745437; called by muse, mutect2, varscan2
- NSUN2 | c.2008G>T p.A670S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.02); catalogued as rs759251595, COSV52954144; called by muse, mutect2, varscan2
- NTRK3 | c.1954G>C p.G652R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.319); catalogued as COSV62303179; called by muse, mutect2, varscan2
- NTSR2 | c.1041C>G p.F347L | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV60991026; called by muse, mutect2, varscan2
- NUDCD1 | c.872T>C p.I291T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV53456783; called by muse, mutect2, varscan2
- OPN4 | c.682T>A p.F228I | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV54116247; called by muse, mutect2, varscan2
- OPN5 | c.657C>A p.Y219* | Nonsense Mutation (SNP) | VAF 20/123 reads (16%) | catalogued as COSV55245422; called by muse, mutect2, varscan2
- OR10K2 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs147190355, COSV59221131; called by muse, mutect2, varscan2
- OR10K2 | c.71A>G p.Q24R | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV59221138; called by muse, mutect2, varscan2
- OR10R2 | c.873C>A p.D291E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100936836; called by muse, mutect2, varscan2
- OR10X1 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as COSV63767313, COSV63767998; called by muse, mutect2, varscan2
- OR10Z1 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV63524741; called by muse, mutect2
- OR11H12 | c.497G>T p.C166F | Missense Mutation (SNP) | VAF 15/489 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.042); catalogued as rs1330263923, COSV73569242; called by muse, mutect2
- OR1E1 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as rs768604385, COSV59458947; called by muse, mutect2, varscan2
- OR2AK2 | c.109G>T p.V37F | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV63552548; called by muse, mutect2, varscan2
- OR2B3 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65850911; called by muse, mutect2, varscan2
- OR2L3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 74/200 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV63454865; called by muse, mutect2, varscan2
- OR2T6 | c.485T>C p.I162T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as COSV63216193; called by muse, mutect2, varscan2
- OR4C6 | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as COSV58603771; called by muse, mutect2, varscan2
- OR4F15 | c.221G>T p.C74F | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as rs760907242, COSV59969005; called by muse, mutect2
- OR51V1 | c.263T>A p.L88Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58314103, COSV58315049; called by muse, mutect2, varscan2
- OR5AR1 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57253736, COSV57253982; called by muse, mutect2, varscan2
- OR5D16 | c.841A>G p.T281A | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.779); catalogued as COSV101004135; called by muse, mutect2
- OR5L2 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV101004378, COSV65723970; called by muse, mutect2
- OR6B2 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV53154135; called by muse, mutect2
- OR6C75 | c.272C>A p.S91Y | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV58552138; called by muse, mutect2
- OR6N2 | c.222_223insT p.A75Cfs*6 | Frame Shift Ins (INS) | VAF 44/234 reads (19%) | catalogued as COSV100210454; called by mutect2, pindel, varscan2
- OR8K1 | c.209G>T p.R70I | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.106); catalogued as COSV54402414, COSV54403507; called by muse, mutect2, varscan2
- PACSIN1 | c.1139C>A p.P380H | Missense Mutation (SNP) | VAF 117/239 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV55059981, COSV55062849; called by muse, mutect2, varscan2
- PAX4 | c.833G>C p.C278S | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV58388573, COSV58389745; called by muse, mutect2
- PCARE | c.1550C>G p.S517* | Nonsense Mutation (SNP) | VAF 16/130 reads (12%) | catalogued as COSV59054810, COSV59055065; called by muse, mutect2, varscan2
- PCDHA8 | c.113A>T p.E38V | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV65336855; called by muse, mutect2, varscan2
- PCDHAC1 | c.1130G>T p.C377F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99169484; called by muse, mutect2
- PCDHGB4 | c.1229G>T p.R410L | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53930479, COSV53943562; called by muse, mutect2, varscan2
- PCK1 | c.584C>A p.S195Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60127570, COSV60127715; called by muse, mutect2, varscan2
- PCLO | c.10015G>C p.G3339R | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs756504811, COSV61625154, COSV61633753; called by muse, mutect2, varscan2
- PDP2 | c.710G>T p.R237I | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61240530; called by muse, mutect2, varscan2
- PDS5A | c.3782G>T p.G1261V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.025); catalogued as COSV57825594; called by muse, mutect2, varscan2
- PDZRN3 | c.3087G>T p.R1029S | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99731793; called by muse, mutect2
- PDZRN3 | c.3086G>C p.R1029T | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55216378, COSV99731800; called by muse, mutect2
- PEX1 | c.1137G>T p.E379D | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV50398101; called by muse, mutect2, varscan2
- PEX5L | c.305C>A p.T102K | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV55845451; called by muse, mutect2, varscan2
- PFKM | c.1127+1G>A p.X376_splice | Splice Site (SNP) | VAF 3/41 reads (7%) | catalogued as COSV56657221; called by muse, mutect2
- PHKB | c.945G>T p.Q315H | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV54520678; called by muse, mutect2, varscan2
- PHLDB2 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV67310965; called by muse, mutect2, varscan2
- PHLDB2 | c.2838G>T p.M946I (on ENST00000393925 / NM_001134439.2; = p.M903I on NM_145753.2) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV101208662; called by muse, mutect2, varscan2
- PHLDB2 | c.2839G>T p.A947S (on ENST00000393925 / NM_001134439.2; = p.A904S on NM_145753.2) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV101208663; called by muse, mutect2, varscan2
- PIK3CG | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV63248254; called by muse, mutect2, varscan2
- PKHD1L1 | c.4618G>T p.E1540* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV101006752; called by muse, mutect2, varscan2
- PKP2 | c.1977C>G p.Y659* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as COSV50730296; called by muse, mutect2
- PLEKHH2 | c.3232G>T p.G1078* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99175061; called by muse, mutect2, varscan2
- PLOD3 | c.1468G>C p.D490H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99778262; called by muse, mutect2
- PNLIPRP1 | c.571A>T p.T191S | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.655); catalogued as COSV62611716; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1106C>A p.T369N | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs866988178, COSV65047913; called by muse, mutect2, varscan2
- PNPLA8 | c.2173G>T p.E725* | Nonsense Mutation (SNP) | VAF 22/90 reads (24%) | catalogued as COSV57552342; called by muse, mutect2, varscan2
- PODXL2 | c.1075C>A p.L359I | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV61065332, COSV61065707; called by muse, mutect2, varscan2
- POLR2B | c.101T>G p.F34C | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58900241; called by muse, mutect2
- POSTN | c.576G>T p.L192F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.968); catalogued as COSV65712893; called by muse, mutect2, varscan2
- POTEH | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as rs768811514, COSV58882579; called by muse, varscan2
- PPM1L | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101534470; called by muse, mutect2, varscan2
- PPP1R16B | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.056); catalogued as COSV55377395; called by muse, mutect2, varscan2
- PPP1R1C | c.48C>A p.F16L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV54715705; called by muse, mutect2, varscan2
- PPP1R3A | c.501G>C p.Q167H | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.163); catalogued as COSV52881943; called by muse, mutect2, varscan2
- PSD2 | c.1118C>A p.P373Q | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV51199603; called by muse, mutect2, varscan2
- PSG5 | c.370A>T p.I124F | Missense Mutation (SNP) | VAF 270/468 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV61654150; called by muse, mutect2, varscan2
- PSG6 | c.41C>A p.T14N | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.579); catalogued as rs535810933, COSV51832822; called by muse, mutect2, varscan2
- PTPN3 | c.2356C>G p.R786G | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52705632, COSV52709603; called by muse, mutect2, varscan2
- PTPRD | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV61944418; called by muse, mutect2, varscan2
- PTPRD | c.2645C>A p.A882D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as COSV61944434; called by muse, mutect2, varscan2
- PTPRZ1 | c.2904T>G p.H968Q | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV66436071, COSV66443678; called by muse, mutect2, varscan2
- PUS1 | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as COSV59034709, COSV59035414; called by muse, mutect2, varscan2
- PYHIN1 | c.1320G>T p.Q440H | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV63722355; called by muse, mutect2
- RAPGEFL1 | c.1016A>G p.Q339R | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.967); catalogued as COSV52863156; called by muse, mutect2
- RBM15B | c.2309G>C p.R770P | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60042749; called by muse, mutect2, varscan2
- RBM5 | c.2071G>C p.A691P | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.625); catalogued as COSV61737442; called by muse, mutect2, varscan2
- RCVRN | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56841422; called by muse, mutect2, varscan2
- REG4 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as COSV56653075, COSV99858796; called by muse, mutect2, varscan2
- RERGL | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV57461669, COSV99968055; called by muse, mutect2, varscan2
- RETREG1 | c.440G>T p.W147L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV60448441; called by muse, mutect2, varscan2
- RFC2 | c.208C>G p.P70A | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50016164; called by muse, mutect2, varscan2
- RFPL2 | c.1103C>A p.T368N | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.25); catalogued as COSV50710810; called by muse, mutect2, varscan2
- RGS9 | c.1329C>A p.S443R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1367653884, COSV52225258; called by muse, mutect2, varscan2
- RNASEL | c.502G>T p.G168W | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62376762; called by muse, mutect2, varscan2
- RNF130 | c.869G>T p.C290F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56150419; called by muse, mutect2, varscan2
- RNF165 | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV53973448; called by muse, mutect2, varscan2
- ROCK1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 84/145 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67695917; called by muse, mutect2, varscan2
- RYR3 | c.7316C>T p.S2439F (on ENST00000389232; = p.S2440F on NM_001036.6) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.685); catalogued as COSV66787863; called by muse, mutect2
- SAMD7 | c.485del p.G162Efs*5 | Frame Shift Del (DEL) | VAF 28/104 reads (27%) | catalogued as COSV59418867; called by mutect2, pindel, varscan2
- SCLT1 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV55405523; called by muse, mutect2, varscan2
- SCN9A | c.923G>C p.G308A | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100314213, COSV57609158; called by muse, mutect2, varscan2
- SERPINB3 | c.1061C>A p.S354* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as COSV52191513; called by muse, mutect2, varscan2
- SF3B2 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as COSV59427912; called by muse, mutect2, varscan2
- SH3BP4 | c.1679G>T p.R560L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV60643831, COSV60645999; called by muse, mutect2, varscan2
- SH3GL2 | c.515A>T p.K172M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66050299; called by muse, mutect2, varscan2
- SH3TC2 | c.2498C>A p.T833N | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV60463007; called by muse, mutect2, varscan2
- SH3TC2 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60463022; called by muse, mutect2, varscan2
- SH3TC2 | c.524A>T p.Q175L | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as CD1411893, COSV60463040; called by muse, mutect2, varscan2
- SHQ1 | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.953); catalogued as COSV57765313; called by muse, mutect2, varscan2
- SIGLEC6 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100585651, COSV58436438; called by muse, mutect2, varscan2
- SLC12A5 | c.564C>A p.Y188* (on ENST00000454036 / NM_001134771.2; = p.Y165* on NM_020708.5) | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as COSV54793183; called by muse, mutect2, varscan2
- SLC16A6 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1555749354, COSV59177281; called by muse, mutect2, varscan2
- SLC17A6 | c.1207G>C p.V403L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV54136149; called by muse, mutect2, varscan2
- SLC1A3 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as COSV54316353; called by muse, mutect2, varscan2
- SLC1A6 | c.1606C>A p.L536I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.108); catalogued as COSV55670120; called by muse, mutect2, varscan2
- SLC22A2 | c.1601G>T p.R534I | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as COSV65269924; called by muse, mutect2, varscan2
- SLC22A7 | c.505T>A p.F169I (on ENST00000372585 / NM_153320.2; = p.F167I on NM_006672.3) | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65354301; called by muse, mutect2
- SLC39A6 | c.1726C>T p.H576Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52369108; called by muse, mutect2, varscan2
- SLC4A11 | c.560T>C p.M187T | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV66261846; called by muse, mutect2, varscan2
- SLC6A15 | c.2066A>C p.N689T | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.044); catalogued as COSV57023345; called by muse, mutect2, varscan2
- SLITRK2 | c.137G>C p.C46S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59425233, COSV59426746; called by muse, mutect2, varscan2
- SLX4 | c.3529G>T p.E1177* | Nonsense Mutation (SNP) | VAF 36/184 reads (20%) | catalogued as COSV53563820; called by muse, mutect2, varscan2
- SMAP1 | c.1355G>C p.W452S (on ENST00000370455 / NM_001044305.3; = p.W425S on NM_021940.5) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV57638785; called by muse, mutect2, varscan2
- SNTG1 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99385794; called by muse, mutect2, varscan2
- SNTG1 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99385797; called by muse, mutect2, varscan2
- SORBS2 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs926463692, COSV52998996; called by muse, mutect2, varscan2
- SPATA31D1 | c.3668C>A p.T1223N | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV61195464; called by muse, mutect2, varscan2
- SPEG | c.5378G>C p.G1793A | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56668330; called by muse, mutect2, varscan2
- SPEM2 | c.910G>T p.G304C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61603853, COSV61604700; called by muse, mutect2, varscan2
- SPTA1 | c.5135C>A p.A1712D | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV63752692; called by muse, mutect2, varscan2
- SPTA1 | c.254C>A p.T85N | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV63752694; called by muse, mutect2, varscan2
- ST8SIA2 | c.820C>A p.R274S | Missense Mutation (SNP) | VAF 11/93 reads (12%) | PolyPhen probably damaging (0.924); catalogued as COSV51568225, COSV51569244; called by muse, mutect2, varscan2
- ST8SIA5 | c.720G>T p.E240D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | PolyPhen probably damaging (0.992); catalogued as COSV59331732; called by muse, mutect2, varscan2
- STOML3 | c.546G>T p.W182C | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65510640; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2497T>C p.S833P | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100562251; called by muse, mutect2, varscan2
- SULT1E1 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs747589749, COSV56947006; called by muse, mutect2, varscan2
- SYT10 | c.1459T>A p.Y487N | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as COSV57340224; called by muse, mutect2, varscan2
- TEX13A | c.1178G>C p.R393T | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV61156130; called by muse, mutect2, varscan2
- TEX15 | c.2545G>T p.V849L (on ENST00000256246; = p.V1232L on NM_001350162.2) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV56346076; called by muse, mutect2, varscan2
- TFCP2 | c.1115C>A p.A372E | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV56932910; called by muse, mutect2, varscan2
- TG | c.3971A>T p.E1324V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV55075314; called by muse, mutect2
- TGFB2 | c.953G>A p.C318Y | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65109197; called by muse, mutect2, varscan2
- TGM6 | c.1967+1G>T p.X656_splice | Splice Site (SNP) | VAF 53/118 reads (45%) | catalogued as COSV52479828; called by muse, mutect2, varscan2
- TIAM2 | c.3811G>C p.E1271Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51640167; called by muse, mutect2, varscan2
- TLDC2 | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV99456170; called by muse, mutect2, varscan2
- TLR10 | c.334A>T p.T112S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58300294; called by muse, mutect2, varscan2
- TMC2 | c.975C>A p.N325K | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs766523674, COSV62652515; called by muse, mutect2, varscan2
- TMC3 | c.1483C>A p.P495T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV100846004; called by muse, mutect2
- TMCC3 | c.328C>A p.R110S | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54154294; called by muse, mutect2, varscan2
- TMEM143 | c.474G>T p.E158D | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1249873202, COSV53156450; called by muse, mutect2, varscan2
- TMEM200A | c.1171C>A p.L391I | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV51652685; called by muse, mutect2, varscan2
- TMEM59L | c.661G>T p.V221L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV53241549, COSV53242186; called by muse, mutect2, varscan2
- TNNT2 | c.783G>T p.Q261H (on ENST00000236918; = p.Q258H on NM_000364.4) | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV52662461; called by muse, mutect2, varscan2
- TP73 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV60701192; called by muse, mutect2, varscan2
- TPO | c.165C>A p.Y55* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as CM1510459, COSV61101360; called by muse, mutect2, varscan2
- TPTE | c.945G>A p.M315I (on ENST00000618007 / NM_199261.4; = p.M297I on NM_199259.4) | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs754298589; called by muse, varscan2
- TRIM51 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV55264031, COSV55266319; called by muse, mutect2, varscan2
- TROAP | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57743993; called by muse, mutect2, varscan2
- TRPC4AP | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV52679600; called by muse, mutect2, varscan2
- TRPM6 | c.3703G>T p.E1235* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV62509554; called by muse, mutect2, varscan2
- TSHZ3 | c.1521G>T p.L507F | Missense Mutation (SNP) | VAF 242/374 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53670889; called by muse, mutect2, varscan2
- TTN | c.41326G>A p.E13776K (on ENST00000591111; = p.E6352K on NM_003319.4) | Missense Mutation (SNP) | VAF 8/126 reads (6%) | PolyPhen probably damaging (0.994); catalogued as COSV60041246; called by muse, mutect2
- TUBGCP3 | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV56186705; called by muse, varscan2
- TWIST1 | c.494G>C p.S165T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV54250607; called by muse, mutect2, varscan2
- UBE4A | c.2803G>T p.D935Y (on ENST00000252108 / NM_001204077.2; = p.D942Y on NM_004788.4) | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52804039; called by muse, mutect2, varscan2
- UHMK1 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs763806630, COSV56420038; called by muse, mutect2, varscan2
- UNC79 | c.7075G>A p.G2359R (on ENST00000393151 / NM_001346218.2; = p.G2182R on NM_020818.5) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56386801; called by muse, varscan2
- USH2A | c.12599G>C p.W4200S | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV56365952; called by muse, mutect2, varscan2
- VIT | c.1088T>A p.I363N (on ENST00000389975 / NM_001177969.1; = p.I378N on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101007731; called by muse, mutect2, varscan2
- VPREB1 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56425704; called by mutect2, varscan2
- VPS13D | c.8092G>T p.A2698S | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV50637090; called by muse, varscan2
- VSTM2A | c.138G>T p.M46I | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV56493893; called by muse, mutect2, varscan2
- WDCP | c.1924G>T p.E642* | Nonsense Mutation (SNP) | VAF 19/122 reads (16%) | catalogued as COSV54592273; called by muse, mutect2, varscan2
- WDR17 | c.3523A>G p.R1175G | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs766138696, COSV54568626; called by mutect2, varscan2
- WT1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.657); catalogued as COSV60071265, COSV60076874; called by muse, mutect2, varscan2
- XIRP2 | c.1354G>A p.D452N (on ENST00000628543; = p.D627N on NM_152381.6) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs376918960; called by muse, mutect2, varscan2
- XIRP2 | c.1999T>C p.C667R (on ENST00000628543; = p.C842R on NM_152381.6) | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1559038310, COSV99746772; called by muse, mutect2
- XPO1 | c.1318G>A p.V440I | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.202); catalogued as rs759110239, COSV101294300; called by muse, mutect2
- XPO1 | c.1317A>T p.E439D | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); catalogued as COSV101294301; called by muse, mutect2, varscan2
- YARS2 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs750357432, COSV61401800, COSV61402481; called by muse, mutect2, varscan2
- YTHDC1 | c.2028T>A p.S676R (on ENST00000344157 / NM_001031732.4; = p.S658R on NM_133370.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.54); PolyPhen probably damaging (0.944); catalogued as COSV60010342; called by muse, mutect2, varscan2
- ZAN | c.5939A>T p.E1980V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV61808694; called by muse, mutect2
- ZBBX | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV56788682; called by muse, mutect2, varscan2
- ZBTB11 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV57245047; called by muse, mutect2
- ZBTB39 | c.1718G>A p.G573E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.795); catalogued as COSV55629286; called by muse, mutect2, varscan2
- ZFP42 | c.594G>T p.K198N | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.773); catalogued as COSV58816733, COSV58817334; called by muse, mutect2, varscan2
- ZNF211 | c.225G>T p.W75C (on ENST00000347302 / NM_198855.4; = p.W88C on NM_006385.5) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV53741789; called by muse, mutect2, varscan2
- ZNF283 | c.1663G>T p.G555C | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.711); catalogued as COSV61031211; called by muse, mutect2, varscan2
- ZNF404 | c.61del p.E21Nfs*3 | Frame Shift Del (DEL) | VAF 72/170 reads (42%) | catalogued as COSV60988062; called by mutect2, pindel, varscan2
- ZNF430 | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55109624; called by muse, mutect2, varscan2
- ZNF488 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.087); catalogued as rs782380361; called by muse, mutect2, varscan2
- ZNF492 | c.1249G>T p.G417* | Nonsense Mutation (SNP) | VAF 10/101 reads (10%) | catalogued as COSV71761934; called by muse, mutect2, varscan2
- ZNF536 | c.571C>A p.R191S | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62823721, COSV62828713; called by muse, mutect2, varscan2
- ZNF780B | c.2276G>T p.G759V | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55463891, COSV55463977; called by muse, mutect2, varscan2
- ZNF827 | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV65226945; called by muse, mutect2, varscan2
- ZP1 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as rs1227296469, COSV53924275; called by muse, mutect2, varscan2
- ZP2 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV54813769; called by muse, mutect2, varscan2
- ZSWIM2 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 9/185 reads (5%) | catalogued as COSV54573647; called by muse, mutect2
- CACNA1B | c.3304del p.E1102Kfs*15 | Frame Shift Del (DEL) | VAF 27/100 reads (27%) | called by mutect2, pindel, varscan2
- DEFB123 | c.168del p.K57Sfs*17 | Frame Shift Del (DEL) | VAF 45/128 reads (35%) | called by mutect2, pindel, varscan2
- GPN3 | c.35dup p.S14Qfs*15 | Frame Shift Ins (INS) | VAF 10/117 reads (9%) | called by mutect2, pindel
- HERC2 | c.7125G>T p.Q2375H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.276); called by mutect2, varscan2
- IGKV1-5 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- IVL | c.140_162del p.V47Gfs*18 | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | called by mutect2, pindel
- JAG1 | c.177_185del p.N60_G62del | In Frame Del (DEL) | VAF 23/73 reads (32%) | called by mutect2, pindel, varscan2
- KCNC2 | c.1087C>A p.R363S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LYZL6 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO1A | c.1957_1958del p.D653Pfs*5 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by pindel, varscan2
- OR2T11 | c.690dup p.R231Sfs*16 | Frame Shift Ins (INS) | VAF 9/25 reads (36%) | called by mutect2, varscan2
- OR8G2P | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 86/171 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- PABPC1 | c.1367C>A p.P456Q | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2
- RBBP7 | c.95_112del p.D32_H37del | In Frame Del (DEL) | VAF 5/43 reads (12%) | called by mutect2, pindel
- RBP3 | c.2702C>T p.A901V | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SORCS3 | c.1903dup p.X635_splice | Splice Site (INS) | VAF 8/28 reads (29%) | called by mutect2, pindel
- TPO | c.659T>A p.V220D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ADAMTS12 | c.3342C>A p.T1114= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV61262430; called by muse, mutect2, varscan2
- ADPRH | c.1017G>A p.E339= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV63694936; called by muse, mutect2, varscan2
- AHNAK2 | c.5118C>A p.L1706= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100318791, COSV60920734; called by muse, mutect2, varscan2
- AIM2 | c.420C>A p.A140= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV100931139; called by muse, mutect2, varscan2
- AKAP9 | c.9015A>G p.L3005= (on ENST00000359028; = p.L2981= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV62345407; called by muse, mutect2, varscan2
- ASB17 | c.810C>A p.T270= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV52409194; called by muse, mutect2, varscan2
- BHLHE40 | c.993A>T p.S331= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV56575519; called by muse, mutect2, varscan2
- BRMS1 | c.465G>T p.T155= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV60820069; called by muse, mutect2, varscan2
- BSN | c.4869A>T p.A1623= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV56517457; called by muse, mutect2, varscan2
- BTBD11 | c.2049C>A p.G683= (on ENST00000280758 / NM_001018072.2; = p.G220= on NM_001017523.2) | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as COSV55023936; called by muse, mutect2, varscan2
- CACNB3 | c.945G>T p.L315= | Silent (SNP) | VAF 85/227 reads (37%) | catalogued as COSV56398302; called by muse, mutect2, varscan2
- CAMLG | c.507G>T p.L169= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV51804663; called by muse, mutect2, varscan2
- CAPRIN2 | c.2754T>A p.R918= | Silent (SNP) | VAF 157/442 reads (36%) | catalogued as COSV51832432; called by muse, mutect2, varscan2
- CASKIN1 | c.312G>C p.A104= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100624069, COSV58872431; called by mutect2, varscan2
- CASS4 | c.1311G>T p.L437= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as rs1387838778, COSV64386370; called by muse, mutect2
- CCDC141 | c.3120A>G p.T1040= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as COSV55373080; called by muse, mutect2, varscan2
- CD1B | c.171C>A p.G57= | Silent (SNP) | VAF 62/425 reads (15%) | catalogued as COSV63804263; called by muse, mutect2, varscan2
- CD1E | c.766C>A p.R256= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as rs775938225, COSV63770003, COSV63770928; called by muse, mutect2, varscan2
- CEP97 | c.1635T>C p.S545= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as COSV59124422; called by muse, mutect2, varscan2
- CHAT | c.2112T>C p.S704= | Silent (SNP) | VAF 48/236 reads (20%) | catalogued as rs1316813571, COSV60324659; called by muse, mutect2, varscan2
- CHD5 | c.3057G>T p.L1019= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV52413918; called by muse, mutect2, varscan2
- CHIT1 | c.663C>A p.V221= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV55146814; called by muse, mutect2, varscan2
- CHST10 | c.498G>A p.R166= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs774342169, COSV51805153; called by muse, mutect2, varscan2
- CNTN1 | c.219G>A p.P73= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as rs1162619112, COSV61639447; called by muse, mutect2, varscan2
- CNTNAP4 | c.2797C>A p.R933= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV56678851, COSV56703566; called by muse, mutect2, varscan2
- COP1 | c.411C>T p.P137= | Silent (SNP) | VAF 25/167 reads (15%) | catalogued as COSV58166867; called by muse, mutect2, varscan2
- COQ8A | c.309G>A p.A103= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs1268268386, COSV64657529; ClinVar: likely benign; called by muse, mutect2, varscan2
- CORIN | c.1593A>T p.A531= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV56691218; called by muse, mutect2, varscan2
- CSMD1 | c.4458G>T p.P1486= (on ENST00000520002; = p.P1485= on NM_033225.6) | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100152066, COSV100153089; called by muse, mutect2, varscan2
- CSMD3 | c.6687G>T p.P2229= (on ENST00000297405 / NM_001363185.1; = p.P2125= on NM_052900.3) | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV52173617; called by muse, mutect2, varscan2
- CST1 | c.117C>A p.L39= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV59055380; called by muse, mutect2, varscan2
- CST8 | c.381C>T p.P127= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as COSV55671091; called by muse, mutect2, varscan2
- CTNNA2 | c.63G>C p.T21= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV63564932; called by muse, mutect2, varscan2
- DDX31 | c.2325G>A p.K775= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs1478343375, COSV55037608; called by muse, mutect2
- DISC1 | c.108G>A p.R36= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV54406562, COSV54418862; called by muse, mutect2, varscan2
- DYSF | c.1977G>T p.V659= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99250113; called by muse, mutect2, varscan2
- ENTPD2 | c.438A>G p.T146= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV57075282; called by muse, mutect2, varscan2
- EPYC | c.294C>A p.P98= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV53799644; called by muse, mutect2, varscan2
- ERN2 | c.1327C>T p.L443= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV56833533; called by muse, mutect2, varscan2
- ERN2 | c.1143G>T p.G381= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as COSV56833540, COSV99891681; called by muse, mutect2, varscan2
- ESR2 | c.549T>C p.Y183= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV50830633; called by muse, mutect2, varscan2
- FAT3 | c.9066G>C p.V3022= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV53107252; called by muse, varscan2
- FHL1 | c.222C>A p.P74= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV61780877; called by muse, mutect2, varscan2
- FLG | c.5412A>C p.S1804= | Silent (SNP) | VAF 30/597 reads (5%) | catalogued as rs1372150358, COSV64241561; called by muse, mutect2
- FOXL1 | c.168G>A p.A56= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV57214219, COSV57215006; called by muse, mutect2, varscan2
- GARS1 | c.1047A>T p.A349= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV66828347; called by muse, mutect2, varscan2
- GCC1 | c.1452G>A p.E484= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV58462483; called by muse, mutect2, varscan2
- GIMAP5 | c.252C>A p.P84= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV100500295, COSV57530214; called by muse, mutect2, varscan2
- GJA8 | c.333G>A p.A111= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs372885882; called by muse, mutect2, varscan2
- GPR39 | c.687G>T p.V229= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV61423287; called by muse, mutect2, varscan2
- GZMB | c.591T>G p.T197= | Silent (SNP) | VAF 6/105 reads (6%) | catalogued as COSV53541240; called by muse, mutect2
- HPN | c.897G>T p.T299= | Silent (SNP) | VAF 38/65 reads (58%) | catalogued as COSV52883522; called by muse, mutect2, varscan2
- IGHV1-58 | c.333C>A p.A111= | Silent (SNP) | VAF 8/204 reads (4%) | called by muse, mutect2
- ITGAX | c.684G>T p.T228= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV51645472; called by muse, mutect2, varscan2
- ITGB8 | c.438T>G p.P146= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV56008128; called by muse, mutect2
- ITPR2 | c.3174A>G p.L1058= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs1159832531, COSV67269003; called by muse, mutect2, varscan2
- KCNA3 | c.1242C>T p.S414= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV63901463; called by muse, mutect2, varscan2
- KIAA1755 | c.807G>A p.Q269= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as COSV54076270; called by muse, mutect2, varscan2
- KRT24 | c.957G>T p.A319= | Silent (SNP) | VAF 23/210 reads (11%) | catalogued as rs776478694, COSV52880215, COSV52880897; called by muse, mutect2, varscan2
- KRTAP9-8 | c.126C>T p.C42= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs1355139347, COSV54199859; called by muse, mutect2, varscan2
- LRP1 | c.2526C>T p.C842= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs1277141239, COSV54510516; called by muse, mutect2
- MAGI1 | c.219G>T p.V73= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV100443206, COSV58325353; called by muse, mutect2, varscan2
- MAP1B | c.5025C>A p.G1675= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs768923611, COSV99702892; called by muse, mutect2
- MAP3K21 | c.1422G>T p.V474= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV64044554; called by muse, mutect2, varscan2
- MLPH | c.336C>A p.V112= | Silent (SNP) | VAF 41/222 reads (18%) | catalogued as COSV52820118, COSV99222566; called by muse, mutect2, varscan2
- MMP10 | c.447C>A p.S149= | Silent (SNP) | VAF 38/187 reads (20%) | catalogued as COSV54246234; called by muse, mutect2, varscan2
- MOB1B | c.390G>T p.T130= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV58673730; called by muse, mutect2, varscan2
- MOS | c.228G>A p.K76= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs377452228; called by muse, mutect2, varscan2
- MYH13 | c.3558C>A p.T1186= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV99355271; called by muse, mutect2
- MYLK3 | c.375C>T p.I125= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs145422318; called by muse, mutect2, varscan2
- MYO1F | c.2433G>A p.K811= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV57794848; called by muse, mutect2, varscan2
- NAV2 | c.4230C>T p.N1410= (on ENST00000396087 / NM_001244963.2; = p.N1387= on NM_145117.5) | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs756746120, COSV60659124; called by muse, mutect2, varscan2
- NAV3 | c.5658A>T p.L1886= (on ENST00000397909 / NM_001024383.2; = p.L1864= on NM_014903.6) | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV57078442; called by muse, mutect2
- NMNAT2 | c.627C>T p.I209= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV54266099, COSV54268263; called by muse, mutect2, varscan2
- NRXN1 | c.1848G>A p.G616= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV58450832; called by muse, mutect2
- OR2C1 | c.399C>T p.T133= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs371716144; called by muse, mutect2
- OR2T33 | c.483C>A p.T161= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs528212559, COSV58815285; called by muse, mutect2, varscan2
- OR4K1 | c.669C>A p.I223= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as rs141997601, COSV53459749; called by muse, mutect2, varscan2
- OR5L1 | c.297G>A p.V99= | Silent (SNP) | VAF 11/149 reads (7%) | catalogued as COSV61733790, COSV61735619; called by muse, mutect2
- OR5T2 | c.768C>G p.S256= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as COSV57589061; called by muse, mutect2, varscan2
- OR6K3 | c.597T>C p.P199= (on ENST00000368146; = p.P183= on NM_001005327.2) | Silent (SNP) | VAF 27/124 reads (22%) | catalogued as COSV63745589; called by muse, mutect2, varscan2
- OR7G3 | c.594G>T p.L198= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV59640369; called by muse, mutect2, varscan2
- OR8J1 | c.396C>T p.Y132= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs1479428233, COSV100275208, COSV57318143; called by muse, mutect2, varscan2
- OR8J3 | c.415C>A p.R139= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as COSV56880340, COSV56883282; called by muse, mutect2, varscan2
- OVCH1 | c.2202T>C p.Y734= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV58962554; called by muse, mutect2
- PCDHA6 | c.1764C>A p.G588= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV65343929; called by muse, mutect2, varscan2
- PCDHGA9 | c.1599G>A p.T533= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as rs764332245, COSV53943574, COSV99544430; called by muse, mutect2, varscan2
- PDE5A | c.2610C>A p.G870= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV53348081; called by muse, mutect2, varscan2
- PKHD1L1 | c.4617A>G p.T1539= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV101006751; called by muse, mutect2, varscan2
- PLD1 | c.2793G>C p.V931= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV60567822; called by muse, mutect2, varscan2
- PLD1 | c.2379G>T p.V793= | Silent (SNP) | VAF 33/199 reads (17%) | catalogued as COSV60567830; called by muse, mutect2, varscan2
- PNPLA3 | c.795C>T p.S265= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV53378184; called by muse, mutect2, varscan2
- PRDM13 | c.195G>T p.L65= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV65029650; called by muse, mutect2, varscan2
- PSMC4 | c.45C>T p.I15= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as rs1158331965, COSV50095021; called by muse, mutect2, varscan2
- PZP | c.2676G>A p.E892= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV54360021; called by muse, varscan2
- RCC1 | c.147G>T p.G49= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV65779434; called by muse, mutect2, varscan2
- RHAG | c.999C>A p.L333= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as COSV57704255; called by muse, mutect2, varscan2
- RNF213 | c.2076G>T p.L692= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV60623424; called by muse, mutect2, varscan2
- RPS6KA5 | c.1548C>T p.F516= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV56221903; called by muse, mutect2
- RRP12 | c.2715G>T p.L905= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV59667362; called by muse, mutect2
- RYR2 | c.13080C>A p.S4360= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100772573; called by muse, mutect2, varscan2
- RYR3 | c.14568C>A p.A4856= (on ENST00000389232; = p.A4857= on NM_001036.6) | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100145761; called by muse, mutect2, varscan2
- S100A3 | c.96G>T p.A32= | Silent (SNP) | VAF 46/224 reads (21%) | catalogued as COSV100573194, COSV62876710; called by muse, mutect2, varscan2
- SCP2 | c.1200A>C p.V400= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV65261077; called by muse, mutect2, varscan2
- SEMA4A | c.921G>T p.A307= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100740634, COSV61772650; called by muse, mutect2, varscan2
- SERPINA7 | c.1062G>C p.V354= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as COSV59665730; called by muse, mutect2, varscan2
- SERPINB5 | c.888C>A p.I296= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV66975096; called by muse, mutect2, varscan2
- SH3GL3 | c.927G>A p.G309= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs749837496, COSV61056480; called by muse, mutect2, varscan2
- SI | c.4611A>G p.S1537= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV52277426; called by muse, mutect2
- SIRT7 | c.426G>A p.E142= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV58711232; called by muse, mutect2
- SLC12A2 | c.1164A>T p.A388= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV52471098; called by muse, mutect2, varscan2
- SLC13A1 | c.426G>T p.S142= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV52010933; called by muse, mutect2, varscan2
- SLC39A11 | c.588G>T p.L196= (on ENST00000542342 / NM_001159770.2; = p.L189= on NM_139177.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as rs751853412, COSV99723898; called by muse, mutect2
- SLC3A1 | c.303C>A p.I101= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV53222489, COSV99576786; called by muse, mutect2, varscan2
- SLC4A11 | c.390A>C p.L130= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as COSV101196124; called by muse, mutect2, varscan2
- SLCO1C1 | c.1467C>A p.P489= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV56872230; called by muse, mutect2, varscan2
- SLITRK2 | c.945G>T p.V315= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2
- SPATA31A1 | c.2034C>G p.T678= | Silent (SNP) | VAF 31/208 reads (15%) | called by muse, mutect2, varscan2
- SPSB4 | c.486G>T p.P162= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs769315844, COSV60147199; called by muse, mutect2
- SSU72P8 | c.327T>C p.F109= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1437007164, COSV66361123; called by muse, mutect2, varscan2
- TEX55 | c.1332C>A p.P444= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV55211057; called by muse, mutect2
- TLDC2 | c.426C>A p.S142= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV99456147; called by muse, mutect2, varscan2
- TRIM2 | c.2001G>A p.G667= (on ENST00000437508; = p.G694= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV58633302; called by muse, mutect2, varscan2
- TTN | c.57058C>T p.L19020= (on ENST00000591111; = p.L11596= on NM_003319.4) | Silent (SNP) | VAF 16/260 reads (6%) | catalogued as COSV60041194, COSV60052977; called by muse, mutect2
- UNC5B | c.2232G>T p.P744= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV58977010; called by muse, mutect2, varscan2
- USP33 | c.1218C>T p.S406= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV62469333; called by muse, mutect2, varscan2
- VIT | c.1089T>A p.I363= (on ENST00000389975 / NM_001177969.1; = p.I378= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/149 reads (12%) | catalogued as COSV101007733; called by muse, mutect2, varscan2
- XYLT1 | c.2634C>A p.V878= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs772538035, COSV54483772; called by mutect2, varscan2
- XYLT1 | c.1149C>A p.V383= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99763138; called by muse, mutect2, varscan2
- ZC3H11A | c.1995A>G p.K665= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV59746208; called by muse, mutect2, varscan2
- ZFP90 | c.1530A>T p.T510= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV68050925; called by muse, mutect2, varscan2
- ZNF2 | c.1023G>T p.L341= (on ENST00000611147 / NM_001291605.2; = p.L328= on NM_021088.4) | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV54636922; called by muse, mutect2, varscan2
- ZSCAN1 | c.171C>A p.G57= | Silent (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- AC244258.1 | n.977C>A | RNA (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3625+279G>T | Intron (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99587755; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847254 A>T | 5'Flank (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- AMZ1 | c.-1C>T | 5'UTR (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100406577; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501843 G>T | 5'Flank (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- ARFRP1 | c.264+700G>C | Intron (SNP) | VAF 25/149 reads (17%) | called by muse, mutect2, varscan2
- DCHS2 | n.7770G>A | RNA (SNP) | VAF 14/88 reads (16%) | catalogued as rs903090049, COSV61771609; called by muse, mutect2, varscan2
- DPP6 | c.627+20974C>A | Intron (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100127858; called by muse, mutect2, varscan2
- DST | c.4296+4812G>T | Intron (SNP) | VAF 20/185 reads (11%) | catalogued as COSV55037187, COSV99759433; called by muse, mutect2, varscan2
- ELP4 | c.1147-19947C>T | Intron (SNP) | VAF 8/74 reads (11%) | catalogued as rs1217209120, COSV100635850; called by muse, mutect2
- FAM107B | c.-52_-51delinsT | 5'UTR (DEL) | VAF 11/71 reads (15%) | called by pindel, varscan2*
- NBPF11 | c.-548-3223G>T | Intron (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- NBPF11 | c.-548-3224G>T | Intron (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- PLPPR5 | c.*1T>A | 3'UTR (SNP) | VAF 14/35 reads (40%) | catalogued as COSV99587838; called by muse, mutect2, varscan2
- PPA2 | c.157+352C>G | Intron (SNP) | VAF 4/49 reads (8%) | catalogued as rs1158877044; called by muse, mutect2, varscan2
- TMEM132E | chr17:34579058 ins G | 5'Flank (INS) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- TPTE2 | c.1395+593G>T | Intron (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
